Somatic mutation profile of tumor specimen TCGA-AL-3468-01A (aliquot TCGA-AL-3468-01A-01D-1252-08) from TCGA case TCGA-AL-3468, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 74.5 years (27,205 days).
Specimen TCGA-AL-3468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c69aca4f-6643-42f4-bec3-3bbe8565f5d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AL-3468-10A (Blood Derived Normal), aliquot TCGA-AL-3468-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94443f6c-fa19-4077-9dc1-3434accfefbe

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Frame Shift Del 8, Frame Shift Ins 4, Nonsense Mutation 3, Intron 2, Splice Region 2, Splice Site 2, 3'Flank 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473653, CM053932; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV55947689; called by muse, mutect2, varscan2
- BHLHE40 | c.766A>T p.S256C | Missense Mutation (SNP) | VAF 86/139 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1387662807; called by muse, mutect2, varscan2
- CAMK2B | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1233579662; called by muse, mutect2, varscan2
- CD180 | c.995A>G p.H332R | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs957136690; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 44/169 reads (26%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- HMSD | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs1204164506; called by muse, mutect2
- HSPD1 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs369172755; called by muse, varscan2
- IGLL5 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.021); catalogued as rs1204573685; called by muse, mutect2, varscan2
- IL18BP | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs762142337; called by muse, varscan2
- KNDC1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs541722509, COSV58845042; called by muse, mutect2, varscan2
- NEK8 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs1324695909; called by muse, mutect2, varscan2
- OR5P2 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs1411675285; called by muse, mutect2
- PRSS55 | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 159/430 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV60807781; called by muse, mutect2, varscan2
- RAB37 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs750256354, COSV61195214; called by muse, mutect2
- SDK1 | c.3563C>G p.T1188S | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as rs949421596; called by muse, mutect2
- SLC2A2 | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as CD972446; called by muse, mutect2, varscan2
- SRCAP | c.5380C>G p.P1794A | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs371358460; called by muse, mutect2, varscan2
- TIMELESS | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs773667829; called by muse, mutect2, varscan2
- TRIP11 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV50924813, COSV99971167; called by muse, varscan2
- ZNF17 | c.1098_1101del p.F366Lfs*91 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | catalogued as rs748385772; called by mutect2, varscan2
- ACADL | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACOX1 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 95/172 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM15 | c.2005A>T p.S669C | Missense Mutation (SNP) | VAF 170/430 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AIFM3 | c.1029G>C p.L343= | Splice Region (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- ARL4A | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ATP7B | c.1236del p.E412Dfs*6 | Frame Shift Del (DEL) | VAF 51/153 reads (33%) | called by mutect2, pindel, varscan2
- BAP1 | c.435C>G p.A145= | Splice Region (SNP) | VAF 63/225 reads (28%) | called by muse, mutect2, varscan2
- BARD1 | c.2110A>C p.S704R | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BPNT1 | c.880_884dup p.S296Mfs*30 | Frame Shift Ins (INS) | VAF 57/272 reads (21%) | called by pindel, varscan2
- BPNT1 | c.878_879insTG p.Y294Afs*31 | Frame Shift Ins (INS) | VAF 106/306 reads (35%) | called by muse*, mutect2, varscan2*
- CACNA1H | c.4880T>C p.I1627T | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CD248 | c.1933del p.I645Sfs*160 | Frame Shift Del (DEL) | VAF 55/146 reads (38%) | called by mutect2, pindel, varscan2
- CDC6 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 105/178 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CELSR1 | c.2023A>G p.I675V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- COL5A3 | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 242/449 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ9 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- CRTC3 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- DPP10 | c.2249C>A p.T750N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DSCAM | c.1615A>G p.K539E | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- EIF4G3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EIF4G3 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EIF5 | c.1220del p.K407Rfs*11 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- GAREM1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GLB1L3 | c.349A>C p.N117H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGSF9 | c.2984C>A p.P995H (on ENST00000368094 / NM_001135050.2; = p.P979H on NM_020789.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ISG20L2 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- KCNS2 | c.1262del p.K421Sfs*16 | Frame Shift Del (DEL) | VAF 97/272 reads (36%) | called by mutect2, pindel, varscan2
- LANCL2 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC1 | c.1442C>A p.P481Q | Missense Mutation (SNP) | VAF 180/203 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP5 | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NR2F2 | c.420_421insT p.K141* | Frame Shift Ins (INS) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- NXF1 | c.944_945insC p.K316Efs*14 | Frame Shift Ins (INS) | VAF 29/81 reads (36%) | called by mutect2, varscan2
- OR2J3 | c.807_808del p.Q271Rfs*16 | Frame Shift Del (DEL) | VAF 73/86 reads (85%) | called by mutect2, pindel, varscan2
- PCSK2 | c.10_12dup p.G4dup | In Frame Ins (INS) | VAF 87/165 reads (53%) | called by mutect2, pindel, varscan2
- PHRF1 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- POLDIP3 | c.476del p.P159Hfs*9 | Frame Shift Del (DEL) | VAF 71/212 reads (33%) | called by mutect2, pindel, varscan2
- PRELID1 | c.548A>C p.K183T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC6A6 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 110/182 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- SLC6A7 | c.733T>C p.F245L | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SMARCA4 | c.3528C>G p.S1176R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SMPD4 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SPATA31D1 | c.4320del p.A1441Lfs*28 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- SPIN3 | c.374C>G p.A125G | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- SSH1 | c.2720A>T p.H907L | Missense Mutation (SNP) | VAF 126/188 reads (67%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- SVEP1 | c.2600-12_2600-1del p.X867_splice | Splice Site (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel
- TAF9B | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TM7SF3 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TMEM67 | c.752A>C p.N251T | Missense Mutation (SNP) | VAF 127/277 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM33 | c.1861C>A p.H621N | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- USP3 | c.1405T>G p.S469A | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ZFP36L1 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF503 | c.1421C>A p.P474Q | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNF658 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 97/237 reads (41%) | called by muse, mutect2, varscan2
- ASH1L | c.5793A>T p.P1931= | Silent (SNP) | VAF 73/206 reads (35%) | called by muse, mutect2, varscan2
- CACNB1 | c.1677G>A p.L559= | Silent (SNP) | VAF 254/815 reads (31%) | called by muse, mutect2, varscan2
- COL5A1 | c.4617T>C p.P1539= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2370A>G p.R790= | Silent (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- FASTKD5 | c.777T>C p.P259= | Silent (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- FRG2B | c.42C>T p.S14= | Silent (SNP) | VAF 109/412 reads (26%) | catalogued as rs774052843, COSV71042421; called by muse, mutect2, varscan2
- ITGB6 | c.1845A>G p.E615= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- KCNC3 | c.288C>T p.G96= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs778044065, COSV65388138; called by muse, mutect2, varscan2
- KIAA0586 | c.2925C>T p.L975= (on ENST00000619416 / NM_001244190.2; = p.L914= on NM_014749.5) | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs1333095624; called by muse, mutect2, varscan2
- LENG8 | c.162T>G p.A54= | Silent (SNP) | VAF 44/103 reads (43%) | called by muse, mutect2, varscan2
- LMF2 | c.2121G>A p.K707= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1209170410; called by muse, mutect2, varscan2
- LTBR | c.291C>T p.I97= | Silent (SNP) | VAF 242/408 reads (59%) | called by muse, mutect2, varscan2
- MEGF8 | c.6363T>C p.C2121= (on ENST00000251268 / NM_001271938.2; = p.C2054= on NM_001410.3) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs754017719; called by muse, mutect2, varscan2
- MSH5 | c.600A>G p.E200= | Silent (SNP) | VAF 56/183 reads (31%) | called by muse, mutect2, varscan2
- PDZRN3 | c.2889G>A p.A963= | Silent (SNP) | VAF 72/263 reads (27%) | catalogued as rs749523844, COSV55191215; called by muse, mutect2, varscan2
- PPP1R12C | c.2133C>G p.L711= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs914299485; called by muse, mutect2
- PRKCE | c.1680T>C p.N560= | Silent (SNP) | VAF 108/260 reads (42%) | catalogued as rs1174558448; called by muse, mutect2, varscan2
- SLC12A9 | c.2226T>C p.D742= | Silent (SNP) | VAF 361/796 reads (45%) | catalogued as rs748908179; called by muse, mutect2, varscan2
- TRAV5 | c.204G>A p.T68= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs766893024; called by muse, mutect2, varscan2
- WWC1 | c.891G>A p.Q297= | Silent (SNP) | VAF 79/161 reads (49%) | catalogued as COSV54656475; called by muse, mutect2, varscan2
- ZHX3 | c.1842C>A p.T614= | Silent (SNP) | VAF 168/269 reads (62%) | called by muse, mutect2, varscan2
- CAMKK2 | c.-68T>A | 5'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- LY9 | c.454+1715del | Intron (DEL) | VAF 102/279 reads (37%) | called by mutect2, pindel, varscan2
- MTRNR2L6 | chr7:142671104 C>A | 3'Flank (SNP) | VAF 84/206 reads (41%) | called by muse, mutect2, varscan2
- SPINK5 | c.2740-127G>T | Intron (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
